Somatic mutation profile of tumor specimen C3L-00093-01 (aliquot CPT0086310009) from CPTAC case C3L-00093, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 66.5 years (24,301 days).
Specimen C3L-00093-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45d450a2-9277-4577-adae-18520cb59b60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00093-31 (Blood Derived Normal), aliquot CPT0087370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e7f5d24-85be-4c6d-b911-2cfe305ddc21

The open-access MAF lists 151 somatic variants for this specimen: 94 protein-altering or splice-affecting, 44 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 44, Intron 5, 3'UTR 4, Nonsense Mutation 3, Translation Start Site 2, 5'Flank 2, Frame Shift Ins 2, 3'Flank 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 156/640 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, varscan2
- KEAP1 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 19/202 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50266507; called by muse, mutect2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 32/379 reads (8%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2
- TP53 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 12/294 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519977, COSV52671863, COSV52706449, COSV52741627, COSV52827803; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ANKRD30B | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs368489461; called by muse, mutect2
- AQP12B | c.33C>G p.F11L | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as rs577637446; called by muse, mutect2
- CFAP251 | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 27/319 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.335); catalogued as rs200928405, COSV56609488; called by muse, mutect2
- CRACR2B | c.626G>A p.R209K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1437267383; called by muse, mutect2
- DNAH5 | c.8426C>T p.S2809L | Missense Mutation (SNP) | VAF 28/456 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs866324367, COSV54208831; called by muse, mutect2
- EGFR | c.2612C>G p.A871G | Missense Mutation (SNP) | VAF 142/558 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs397517134, COSV51774247, COSV51780429, COSV99292321; ClinVar: uncertain significance; called by muse, varscan2
- FAM43A | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.039); catalogued as rs1410227474; called by muse, mutect2
- FAT4 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 21/281 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1165902550, COSV67882453; called by muse, mutect2
- FFAR3 | c.954G>C p.Q318H | Missense Mutation (SNP) | VAF 84/534 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59908932; called by mutect2, varscan2
- FLAD1 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 43/420 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52696619; called by muse, mutect2, varscan2
- FRY | c.7529G>T p.S2510I | Missense Mutation (SNP) | VAF 51/411 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV66569125; called by muse, mutect2, varscan2
- GRM2 | c.1375C>G p.L459V | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as COSV99622554; called by muse, mutect2
- H3-5 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 38/397 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs376467484; called by muse, mutect2
- JCAD | c.3800C>T p.S1267L | Missense Mutation (SNP) | VAF 47/414 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1439071639; called by muse, mutect2, varscan2
- KCNH6 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 22/426 reads (5%) | catalogued as COSV59001536; called by muse, mutect2
- KRT13 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 38/334 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as rs746117318, COSV55839059; called by muse, mutect2, varscan2
- LRRC66 | c.1418G>C p.R473T | Missense Mutation (SNP) | VAF 36/271 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.686); catalogued as COSV58632991; called by muse, mutect2, varscan2
- MKKS | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV61398915; called by muse, mutect2, varscan2
- MTRES1 | c.220C>G p.P74A | Missense Mutation (SNP) | VAF 32/377 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as COSV60967658; called by muse, mutect2
- NEK5 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs866677635; called by muse, mutect2
- NPHP3 | c.982A>C p.M328L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV58128481; called by muse, mutect2
- PCDHB14 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53386468; called by muse, mutect2
- PDE3A | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.041); catalogued as rs746694508, COSV100762198, COSV62981293; called by muse, mutect2, varscan2
- PGAP6 | c.1655C>T p.T552M | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374093452; called by muse, mutect2, varscan2
- PLXNA2 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV100885917; called by muse, mutect2
- PRRT2 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV54886453; called by muse, mutect2
- RNLS | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 24/327 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.079); catalogued as COSV59291566; called by muse, mutect2
- SDK1 | c.3803G>A p.R1268Q | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.117); catalogued as rs750500679, COSV67371383; called by muse, mutect2
- SH3BGR | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 42/443 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV61323508; called by muse, mutect2
- SNRPN | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs1445289983; called by muse, mutect2
- SOX21 | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 69/675 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs1298877629; called by muse, mutect2, varscan2
- SRSF6 | c.229C>G p.R77G | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs762641128; called by muse, mutect2, varscan2
- TRIM21 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 27/384 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV54343484; called by muse, mutect2
- ABCG5 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 51/617 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2
- ACAP2 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AKAP9 | c.789dup p.L264Tfs*15 | Frame Shift Ins (INS) | VAF 92/437 reads (21%) | called by mutect2, pindel, varscan2
- AP1G2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- BMP5 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 46/518 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BPNT2 | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- C19orf71 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- CBLL1 | c.949C>G p.H317D | Missense Mutation (SNP) | VAF 15/423 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.469); called by muse, mutect2
- CD180 | c.724C>G p.L242V | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); called by muse, mutect2
- CILP | c.513G>T p.Q171H | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- CUL7 | c.1997dup p.L667Pfs*13 | Frame Shift Ins (INS) | VAF 60/412 reads (15%) | called by mutect2, pindel, varscan2
- DGKD | c.2527A>G p.I843V (on ENST00000264057 / NM_152879.3; = p.I799V on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DPP10 | c.667T>G p.F223V | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- GPR42 | c.954G>C p.Q318H | Missense Mutation (SNP) | VAF 177/761 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, varscan2
- GRPEL2 | c.285G>C p.Q95H | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- HAL | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- IL17RD | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.026); called by muse, mutect2
- IMPDH2 | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KALRN | c.562C>T p.L188F | Missense Mutation (SNP) | VAF 57/461 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- KAZN | c.1612C>A p.L538M | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- KIF16B | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KLHL11 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.125); called by muse, mutect2
- LRRC39 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/272 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- MDN1 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 18/320 reads (6%) | called by muse, mutect2
- MGAM2 | c.5916C>A p.S1972R | Missense Mutation (SNP) | VAF 44/408 reads (11%) | SIFT tolerated, low confidence (0.22); called by muse, mutect2, varscan2
- MIOS | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 15/403 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2
- MKKS | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- MOG | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 26/309 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYO1H | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2
- NAV1 | c.5191G>C p.E1731Q | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBEAL2 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- OPCML | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 19/268 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OTC | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 42/562 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PDGFRA | c.2423T>A p.F808Y | Missense Mutation (SNP) | VAF 68/458 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PDK1 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PRPF3 | c.426C>G p.I142M | Missense Mutation (SNP) | VAF 20/500 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2
- RAD50 | c.481G>C p.D161H | Missense Mutation (SNP) | VAF 21/281 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2
- RPN1 | c.1604C>G p.S535C | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.524); called by muse, mutect2
- SCN2A | c.1740C>G p.F580L | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.87); called by muse, mutect2
- SHISA2 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.389); called by muse, mutect2
- SHLD1 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 13/257 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.096); called by muse, mutect2
- SLC45A2 | c.660C>G p.F220L | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2
- SLC8A2 | c.463T>C p.F155L | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STRADA | c.769G>A p.D257N (on ENST00000336174 / NM_001363786.1; = p.D220N on NM_153335.6) | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SUCO | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2
- SYNE2 | c.8662G>C p.D2888H | Missense Mutation (SNP) | VAF 21/330 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2
- TENM4 | c.5879A>T p.N1960I | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TJP3 | c.2032G>A p.V678M | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TNIK | c.2962G>A p.D988N | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.014); called by muse, mutect2
- TRDN | c.1187-1G>C p.X396_splice | Splice Site (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- TRPS1 | c.1405C>G p.P469A (on ENST00000220888 / NM_001330599.2; = p.P482A on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/494 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.138); called by muse, mutect2
- TUSC1 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.818); called by muse, mutect2
- UNC13B | c.3223G>A p.E1075K | Missense Mutation (SNP) | VAF 21/313 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2
- VPS36 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2
- XPO4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/89 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2
- ZFAND4 | c.1701C>G p.I567M | Missense Mutation (SNP) | VAF 27/379 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.38); called by muse, mutect2
- ZNF629 | c.1736A>G p.N579S | Missense Mutation (SNP) | VAF 43/418 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ADAM22 | c.2403G>A p.K801= | Silent (SNP) | VAF 30/281 reads (11%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3843C>G p.L1281= (on ENST00000370717 / NM_001366005.1; = p.L1225= on NM_012302.4) | Silent (SNP) | VAF 36/301 reads (12%) | catalogued as COSV54658461; called by muse, mutect2, varscan2
- AKAP9 | c.11334G>A p.V3778= (on ENST00000359028; = p.V3754= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/376 reads (7%) | called by muse, mutect2
- ANGEL2 | c.507G>A p.V169= | Silent (SNP) | VAF 26/316 reads (8%) | catalogued as COSV100853917; called by muse, mutect2
- ANKRD11 | c.1506C>T p.L502= | Silent (SNP) | VAF 42/380 reads (11%) | called by muse, mutect2, varscan2
- APOA5 | c.711C>G p.L237= | Silent (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- ARNT | c.627C>T p.L209= | Silent (SNP) | VAF 26/290 reads (9%) | catalogued as COSV100591416; called by muse, mutect2
- ASL | c.1047C>T p.V349= | Silent (SNP) | VAF 42/728 reads (6%) | called by muse, mutect2
- CACNA1S | c.2424C>T p.F808= | Silent (SNP) | VAF 16/346 reads (5%) | called by muse, mutect2
- CCDC168 | c.11493G>A p.R3831= | Silent (SNP) | VAF 18/166 reads (11%) | called by muse, mutect2, varscan2
- CDK13 | c.1809C>T p.V603= | Silent (SNP) | VAF 38/321 reads (12%) | called by muse, mutect2, varscan2
- CILK1 | c.1131C>G p.L377= | Silent (SNP) | VAF 18/215 reads (8%) | called by muse, mutect2
- CLCNKA | c.1728G>A p.V576= | Silent (SNP) | VAF 20/410 reads (5%) | called by muse, mutect2
- DBH | c.801C>T p.F267= | Silent (SNP) | VAF 36/329 reads (11%) | called by muse, mutect2, varscan2
- DOCK3 | c.1047C>T p.N349= | Silent (SNP) | VAF 18/178 reads (10%) | catalogued as rs373679041; called by muse, mutect2, varscan2
- EPB41 | c.2064G>A p.L688= (on ENST00000343067 / NM_001166005.2; = p.L446= on NM_004437.4) | Silent (SNP) | VAF 13/303 reads (4%) | called by muse, mutect2
- EPB41L2 | c.861A>G p.P287= | Silent (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- EPHB6 | c.1923C>T p.L641= | Silent (SNP) | VAF 38/562 reads (7%) | catalogued as rs377257395, COSV63893050; called by muse, mutect2
- FAM151A | c.1143C>T p.P381= | Silent (SNP) | VAF 15/171 reads (9%) | catalogued as rs760588689; called by muse, mutect2
- FAM160A1 | c.783A>T p.L261= | Silent (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- FXYD1 | c.144C>T p.F48= | Silent (SNP) | VAF 131/336 reads (39%) | catalogued as rs762504988, COSV54343680; called by muse, mutect2, varscan2
- IFNE | c.540C>T p.F180= | Silent (SNP) | VAF 22/351 reads (6%) | called by muse, mutect2
- INSYN2B | c.1155G>A p.R385= | Silent (SNP) | VAF 19/316 reads (6%) | catalogued as COSV99911610; called by muse, mutect2
- INTS7 | c.1650G>T p.L550= | Silent (SNP) | VAF 43/364 reads (12%) | called by muse, mutect2, varscan2
- KIF14 | c.3300C>T p.I1100= | Silent (SNP) | VAF 14/188 reads (7%) | catalogued as COSV100950726; called by muse, mutect2
- LAMC3 | c.1725G>A p.L575= | Silent (SNP) | VAF 25/209 reads (12%) | catalogued as COSV63093132; called by muse, mutect2, varscan2
- MCIDAS | c.969C>T p.F323= | Silent (SNP) | VAF 26/334 reads (8%) | called by muse, mutect2
- MKI67 | c.7446C>G p.L2482= | Silent (SNP) | VAF 22/242 reads (9%) | called by muse, mutect2
- MME | c.1329G>A p.L443= | Silent (SNP) | VAF 18/436 reads (4%) | called by muse, mutect2
- NLRP3 | c.801G>A p.Q267= | Silent (SNP) | VAF 19/210 reads (9%) | called by muse, mutect2
- NXPH1 | c.627C>T p.L209= | Silent (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- OR5M3 | c.183C>T p.L61= | Silent (SNP) | VAF 21/222 reads (9%) | catalogued as rs1223704586; called by muse, mutect2
- PADI6 | c.1725G>A p.T575= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as rs113380913; called by muse, mutect2, varscan2
- PCDHA9 | c.1629G>A p.P543= | Silent (SNP) | VAF 78/900 reads (9%) | catalogued as COSV65326130; called by muse, mutect2
- PCDHGA5 | c.870G>A p.E290= | Silent (SNP) | VAF 24/260 reads (9%) | called by muse, mutect2
- PCMTD2 | c.381C>T p.F127= | Silent (SNP) | VAF 15/247 reads (6%) | called by muse, mutect2
- PDE5A | c.537G>A p.L179= | Silent (SNP) | VAF 36/293 reads (12%) | catalogued as rs749403936; called by muse, mutect2, varscan2
- PLCE1 | c.2247C>T p.F749= | Silent (SNP) | VAF 16/365 reads (4%) | called by muse, mutect2
- PLEKHA2 | c.111C>T p.N37= | Silent (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- RASSF5 | c.84G>A p.L28= | Silent (SNP) | VAF 16/272 reads (6%) | called by muse, mutect2
- RYR2 | c.3153C>T p.R1051= | Silent (SNP) | VAF 18/181 reads (10%) | catalogued as rs397516524; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely benign; called by muse, mutect2, varscan2
- SYT9 | c.216C>T p.F72= | Silent (SNP) | VAF 31/347 reads (9%) | catalogued as rs772136021, COSV59615123; called by muse, mutect2
- TBRG1 | c.840G>A p.G280= | Silent (SNP) | VAF 10/171 reads (6%) | catalogued as rs1474245232; called by muse, mutect2
- TREX2 | c.432G>T p.L144= (on ENST00000334497; = p.L101= on NM_080701.3) | Silent (SNP) | VAF 19/147 reads (13%) | called by muse, mutect2
- ADD1 | c.886-27C>A | Intron (SNP) | VAF 22/404 reads (5%) | called by muse, mutect2
- ATR | c.6897+9C>G | Intron (SNP) | VAF 50/328 reads (15%) | called by muse, mutect2, varscan2
- C19orf54 | c.*331C>T | 3'UTR (SNP) | VAF 31/854 reads (4%) | called by muse, mutect2
- CAMK2B | c.1597+744C>A | Intron (SNP) | VAF 30/491 reads (6%) | called by muse, mutect2
- DCP2 | chr5:112976718 C>T | 5'Flank (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2
- DMD | c.*103G>C | 3'UTR (SNP) | VAF 30/314 reads (10%) | catalogued as COSV100628136; called by muse, mutect2
- EEF1B2 | c.203+167C>T | Intron (SNP) | VAF 28/312 reads (9%) | called by muse, mutect2
- FAS | c.*591G>A | 3'UTR (SNP) | VAF 28/434 reads (6%) | called by muse, mutect2
- LAMTOR1 | c.*44C>G | 3'UTR (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2
- MPPED1 | c.-2C>T | 5'UTR (SNP) | VAF 34/236 reads (14%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157674 G>A | 3'Flank (SNP) | VAF 74/956 reads (8%) | catalogued as rs782058641; called by muse, mutect2
- PCGF2 | chr17:38749692 C>A | 5'Flank (SNP) | VAF 11/219 reads (5%) | called by muse, mutect2
- SMARCC2 | c.1651-259G>A | Intron (SNP) | VAF 23/348 reads (7%) | catalogued as COSV57214879; called by muse, mutect2
